Surgical pathology report (de-identified scan), TCGA case TCGA-R5-A7ZR, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-R5-A7ZR-01A (Primary Tumor).

[page 1 of 3]
Specimen Date/Time:

DIAGNOSIS

(A) DUODENUM NODULE:

Active chronic inflammation with fat vacuoles in surface epithelium.
No tumor identified.

(B) STOMACH, BODY TUMOR, BIOPSY:

INFILTRATING, MODERATELY DIFFERENTIATED ADENOCARCINOMA.

No non-neoplastic columnar epithelium or Helicobacter pylori (H&E stain) identified.

(C) STOMACH, NODULAR MUCOSA IN FUNDUS, BIOPSY:

Oxyntic/fundic mucosa with inactive chronic gastritis.

No Helicobacter pylori (H&E stain) or tumor identified.

(D) STOMACH, POLYP IN FUNDUS, BIOPSY:

Superficial fragments of inflammatory/hyperplastic polyp.

No Helicobacter pylori (H&E stain) or tumor identified.

Entire report and diagnosis completed by

CCF
ICD-O-3
Adenocarcinoma, tubular 8211/3
Adenocarcinoma NOS 8140/3
Site Body of stomach C16.2
9/10/9/13

GROSS DESCRIPTION

(A) DUODENAL NODULE - A single 0.4 x 0.3 x 0.2 cm pink-tan soft tissue fragment is entirely submitted in A.

(B) GASTRIC BODY TUMOR - Four tan-red soft tissue fragments have an aggregate dimension of 0.6 x 0.4 x 0.2 cm and are entirely submitted in B.

(C) NODULAR MUCOSA IN FUNDUS - Three tan soft tissue fragments have an aggregate dimension of 0.7 x 0.5 x 0.2 cm and are entirely submitted in C.

(D) POLYP IN FUNDUS - A single 0.2 x 0.2 x 0.1 cm tan-red soft tissue fragment which is entirely submitted in A.

CLINICAL HISTORY

Gastric cancer.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Released by:

-----END OF REPORT-----

[page 2 of 3]
Page: 2

Specimen Date/Time:

PWTSS, dx discrepancy from status
TCGA tumor to be Intrauterine adeno,
tubular type.

Case's (circle):	SE	DISQUALIFIED

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form 4.05

Study Subject ID:		Person ID:	N/A
Study/Site:	TCGA Stomach adenocarcinoma - adenocarcinoma)	Age:	N/A
Event:	PathDiscrepancy	Date of Birth:	
Interviewer:		Sex:	F

Tumor Identifier Provided on Initial Case Quality Control Form

Provide the tumor identifier documented on the initial case quality control form for this case.

Pathologic Diagnosis Provided on Initial Pathology Report MODERATELY DIFFERENTIATED ADENOCARCINOMA

Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.

Histologic features of the sample provided for TCGA, as reflected on the CQCF Intestinal Adenocarcinoma Tubular Type

Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form

The pathologists at always use the gastric cancer classification as intestinal and diffuse (which is so as per TCGA).

do not Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.

Name of TSS Reviewing Pathologist or Biorepository Director

Provide the name of the pathologist who reviewed this case for TCGA.

Source: NCI Genomic Data Commons file dd87d949-7222-4597-86a6-a4204d542238 (TCGA-R5-A7ZR.EB5A03FC-7AA2-454F-AC90-AD3A535E6224.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).